Somatic mutation profile of cancer-model specimen HCM-CSHL-0603-C18-85M (3D Organoid, passage 9; aliquot HCM-CSHL-0603-C18-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0603-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.7 years (25,459 days).
Specimen HCM-CSHL-0603-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0e122d5-7eff-40fb-b3af-286574ed48b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0603-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0603-C18-11A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f183da22-022f-4102-9454-bfd008080970

The open-access MAF lists 132 somatic variants for this specimen: 92 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 39, Nonsense Mutation 9, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4067C>G p.S1356* | Nonsense Mutation (SNP) | VAF 450/451 reads (100%) | catalogued as rs1554085480, COSV57325773, COSV57330189, COSV57333960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MITF | c.940C>T p.R314* (on ENST00000448226 / NM_006722.3; = p.R214* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 138/422 reads (33%) | catalogued as rs104893746, CM960962, COSV58832470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 834/834 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 364/709 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs548685556; called by muse, mutect2, varscan2
- ANGPTL5 | c.813T>A p.F271L | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs1394400156, COSV57533089; called by muse, mutect2
- ANP32D | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 388/589 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs755224166; called by muse, mutect2, varscan2
- AREL1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 148/317 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs748782547; called by muse, mutect2, varscan2
- ARFGAP1 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 535/1062 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.179); catalogued as rs1199118666; called by muse, mutect2, varscan2
- BX276092.9 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 513/514 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs932057518; called by muse, mutect2, varscan2
- C8orf34 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 112/869 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1224787592; called by muse, mutect2, varscan2
- CATSPERG | c.2949G>T p.W983C | Missense Mutation (SNP) | VAF 394/622 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53052685; called by muse, mutect2, varscan2
- CCN1 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 606/607 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs376836267; called by muse, mutect2, varscan2
- CDH18 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs1438635861; called by muse, mutect2, varscan2
- CFAP299 | c.243G>A p.K81= | Splice Region (SNP) | VAF 105/254 reads (41%) | catalogued as rs1276417011; called by muse, mutect2, varscan2
- COL6A3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 187/619 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs201249839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSF | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 141/672 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs748168574; called by muse, mutect2, varscan2
- CYB5R4 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 400/829 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs1290013499; called by muse, mutect2, varscan2
- ERCC4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 220/1014 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377014538, COSV100318824; called by muse, mutect2, varscan2
- FBXO34 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 473/475 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV58254186; called by muse, mutect2, varscan2
- GABRB2 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777977171; called by muse, mutect2, varscan2
- GMEB2 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 172/763 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs779093678; called by muse, mutect2, varscan2
- GNPTAB | c.3388G>A p.V1130I | Missense Mutation (SNP) | VAF 180/554 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768634271; called by muse, mutect2, varscan2
- GPC6 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 557/558 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1357289814, COSV65494787, COSV65525111; called by muse, varscan2
- HTR4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 1050/1051 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140360260; called by muse, mutect2, varscan2
- HYDIN | c.6394G>A p.E2132K | Missense Mutation (SNP) | VAF 345/719 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as rs373417090; called by muse, mutect2, varscan2
- LENG8 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 952/1424 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs770407646, COSV100458166; called by muse, mutect2, varscan2
- LMTK3 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 652/999 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as rs1284386412; called by muse, mutect2, varscan2
- LRRK2 | c.7567C>T p.R2523* | Nonsense Mutation (SNP) | VAF 205/314 reads (65%) | catalogued as rs755698334; called by muse, mutect2, varscan2
- MAGEE1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 776/788 reads (98%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs781822926; called by muse, mutect2, varscan2
- MAGEL2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 743/764 reads (97%) | SIFT deleterious, low confidence (0.02); catalogued as rs1002045692, COSV58568454; called by muse, mutect2, varscan2
- MMUT | c.1824G>A p.M608I | Missense Mutation (SNP) | VAF 333/656 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51273902; called by muse, mutect2, varscan2
- MRPS2 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 573/842 reads (68%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs1276524120; called by muse, mutect2, varscan2
- MUC4 | c.13709G>A p.R4570Q (on ENST00000463781 / NM_018406.7; = p.R334Q on NM_004532.6) | Missense Mutation (SNP) | VAF 405/1281 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767767811; called by muse, mutect2, varscan2
- MYO7B | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 164/583 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs899010523, COSV67348524; called by muse, mutect2, varscan2
- NDST1 | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 203/1221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55787640; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 286/904 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- OLFM1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 48/1007 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs549196080, COSV52961914; called by muse, mutect2
- OR4K2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 190/735 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs748394926, COSV53848232; called by muse, mutect2, varscan2
- OTOP3 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 846/847 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172697; called by muse, mutect2, varscan2
- PIGN | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 209/426 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759600092, COSV104414650, COSV62948506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH1 | c.3935G>A p.R1312H (on ENST00000340059 / NM_001130960.2; = p.R1304H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 265/777 reads (34%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs777459311, COSV58211499; called by muse, mutect2, varscan2
- PPM1D | c.1262C>G p.S421* | Nonsense Mutation (SNP) | VAF 397/397 reads (100%) | catalogued as COSV59959014; called by muse, mutect2, varscan2
- PXDNL | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 277/1740 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759582960, COSV99080550; called by muse, mutect2, varscan2
- RBMXL3 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 641/644 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as rs912004716; called by muse, mutect2, varscan2
- RYR1 | c.7029C>T p.G2343= | Splice Region (SNP) | VAF 473/688 reads (69%) | catalogued as rs138617219; called by muse, mutect2, varscan2
- RYR2 | c.6380G>A p.R2127Q | Missense Mutation (SNP) | VAF 557/557 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516547, CM1313841, COSV63669324, COSV63693748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A16 | c.2161C>A p.L721I | Missense Mutation (SNP) | VAF 265/750 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.81); catalogued as COSV60026828; called by muse, mutect2, varscan2
- SLITRK5 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 541/541 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs1338203946; called by muse, mutect2, varscan2
- SPON1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 264/794 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.37); catalogued as rs782203330; called by muse, mutect2, varscan2
- SZT2 | c.3568G>A p.V1190I (on ENST00000634258 / NM_001365999.1; = p.V1133I on NM_015284.4) | Missense Mutation (SNP) | VAF 200/438 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs779500330; called by muse, mutect2, varscan2
- TCF7L2 | c.1462C>T p.R488C (on ENST00000355995 / NM_001367943.1; = p.R465C on NM_030756.5) | Missense Mutation (SNP) | VAF 178/582 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1264066389, COSV53335962, COSV53336193; called by muse, mutect2, varscan2
- TMEM132D | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 221/791 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs942395156, COSV70592927; called by muse, mutect2, varscan2
- TMEM200C | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 121/434 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356262863, COSV67309243; called by muse, mutect2, varscan2
- TSHZ2 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 546/1026 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772650306, COSV61588904; called by muse, mutect2, varscan2
- VSTM2L | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 382/408 reads (94%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs757359740, COSV65096623; called by mutect2, varscan2
- ZNF773 | c.1270T>G p.F424V | Missense Mutation (SNP) | VAF 467/715 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56590949; called by muse, mutect2, varscan2
- ZSCAN22 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 235/709 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.243); catalogued as rs375935212; called by muse, mutect2, varscan2
- ABCC11 | c.3763T>C p.F1255L | Missense Mutation (SNP) | VAF 205/690 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC9 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 198/652 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- APBA1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 752/1103 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- APPBP2 | c.307A>T p.R103W | Missense Mutation (SNP) | VAF 723/723 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ARMC3 | c.1000A>T p.I334F | Missense Mutation (SNP) | VAF 181/641 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- BBS10 | c.1832A>C p.H611P | Missense Mutation (SNP) | VAF 199/597 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- BLVRB | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 143/454 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CDH22 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 312/1300 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CHST15 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 224/611 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX6 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 155/562 reads (28%) | called by muse, mutect2, varscan2
- DNAH11 | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 156/634 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAH8 | c.8473G>T p.G2825* | Nonsense Mutation (SNP) | VAF 333/694 reads (48%) | called by muse, mutect2, varscan2
- DOCK3 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 481/721 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- EHBP1L1 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 419/668 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH3 | c.3873T>A p.D1291E | Missense Mutation (SNP) | VAF 283/594 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPD2 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 441/441 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNMB1 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 774/774 reads (100%) | SIFT tolerated (0.9); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KMT2C | c.5704G>C p.V1902L | Missense Mutation (SNP) | VAF 85/708 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KRTAP19-4 | c.67T>C p.Y23H | Missense Mutation (SNP) | VAF 223/651 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LYST | c.11296T>A p.L3766M | Missense Mutation (SNP) | VAF 217/639 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 222/702 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYH13 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 118/533 reads (22%) | called by muse, mutect2, varscan2
- RNF6 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 2054/2055 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCN9A | c.2790G>T p.E930D (on ENST00000303354; = p.E919D on NM_002977.3) | Missense Mutation (SNP) | VAF 213/712 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC13A1 | c.1581C>A p.F527L | Missense Mutation (SNP) | VAF 194/708 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SLC9A7 | c.1852C>G p.P618A | Missense Mutation (SNP) | VAF 230/499 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SNX13 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 131/453 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SOCS6 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 267/469 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 329/1036 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.993C>A p.D331E | Missense Mutation (SNP) | VAF 387/388 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRMT11 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TSPO2 | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 172/1120 reads (15%) | called by muse, mutect2, varscan2
- TTC34 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 922/924 reads (100%) | SIFT tolerated (1); PolyPhen possibly damaging (0.691); called by muse, varscan2
- XIRP1 | c.5119C>T p.Q1707* | Nonsense Mutation (SNP) | VAF 510/747 reads (68%) | called by muse, mutect2, varscan2
- ZSCAN16 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 205/760 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ACTL7B | c.435C>T p.H145= | Silent (SNP) | VAF 571/865 reads (66%) | catalogued as rs149121708, COSV65926845; called by muse, mutect2, varscan2
- AMER2 | c.918C>T p.A306= | Silent (SNP) | VAF 324/1953 reads (17%) | called by muse, mutect2, varscan2
- AMER2 | c.441C>T p.P147= | Silent (SNP) | VAF 218/1549 reads (14%) | catalogued as rs777373064; called by muse, mutect2, varscan2
- ATAD2B | c.138C>T p.S46= | Silent (SNP) | VAF 1023/1024 reads (100%) | called by muse, mutect2, varscan2
- BEND4 | c.186C>T p.F62= | Silent (SNP) | VAF 30/639 reads (5%) | catalogued as rs1375938460; called by muse, mutect2
- BHLHE22 | c.915C>A p.R305= | Silent (SNP) | VAF 212/1621 reads (13%) | called by muse, mutect2, varscan2
- CAMTA2 | c.3393C>A p.I1131= | Silent (SNP) | VAF 34/994 reads (3%) | called by muse, mutect2
- CCDC42 | c.789G>A p.T263= | Silent (SNP) | VAF 226/818 reads (28%) | catalogued as rs750499748, COSV53448547; called by muse, mutect2, varscan2
- COL6A6 | c.5112A>G p.G1704= | Silent (SNP) | VAF 150/564 reads (27%) | called by muse, mutect2, varscan2
- DNAH8 | c.3786G>C p.V1262= | Silent (SNP) | VAF 104/502 reads (21%) | called by muse, mutect2, varscan2
- FBN3 | c.1098C>T p.F366= | Silent (SNP) | VAF 268/862 reads (31%) | catalogued as rs751393494, COSV54460543; called by muse, mutect2, varscan2
- GOLGA6L9 | c.231C>T p.G77= | Silent (SNP) | VAF 360/1032 reads (35%) | called by muse, mutect2, varscan2
- GPR153 | c.183C>T p.I61= | Silent (SNP) | VAF 294/822 reads (36%) | catalogued as rs374113239; called by muse, varscan2
- HAUS6 | c.24T>A p.A8= | Silent (SNP) | VAF 330/526 reads (63%) | called by muse, mutect2, varscan2
- LAMA5 | c.4131C>T p.L1377= | Silent (SNP) | VAF 310/670 reads (46%) | catalogued as rs748356543; called by muse, mutect2, varscan2
- LRRC55 | c.618C>G p.P206= | Silent (SNP) | VAF 153/695 reads (22%) | called by muse, mutect2, varscan2
- LRRK1 | c.5211G>A p.T1737= | Silent (SNP) | VAF 601/1206 reads (50%) | catalogued as rs376774894; called by muse, mutect2, varscan2
- MSH3 | c.2274C>T p.N758= | Silent (SNP) | VAF 209/209 reads (100%) | called by muse, mutect2, varscan2
- NIM1K | c.639C>T p.G213= | Silent (SNP) | VAF 333/725 reads (46%) | catalogued as rs1368386873, COSV58143400; called by muse, mutect2, varscan2
- NPIPB11 | c.3372C>T p.P1124= | Silent (SNP) | VAF 172/2448 reads (7%) | catalogued as rs1203578167; called by muse, varscan2
- NT5DC3 | c.48G>A p.R16= | Silent (SNP) | VAF 303/874 reads (35%) | called by muse, mutect2, varscan2
- OBSCN | c.13128C>T p.D4376= | Silent (SNP) | VAF 1051/1052 reads (100%) | catalogued as rs775668321, COSV52844840; called by muse, mutect2, varscan2
- OR1L4 | c.363C>T p.I121= | Silent (SNP) | VAF 449/706 reads (64%) | catalogued as rs747303306, COSV52341060; called by muse, varscan2
- PLPPR2 | c.924C>T p.P308= | Silent (SNP) | VAF 52/950 reads (5%) | called by muse, mutect2
- PLRG1 | c.1158A>G p.T386= | Silent (SNP) | VAF 99/249 reads (40%) | called by muse, mutect2
- PLXDC1 | c.1368G>A p.A456= | Silent (SNP) | VAF 201/572 reads (35%) | catalogued as rs61742536, COSV59551231; called by muse, mutect2, varscan2
- PWWP2B | c.1266G>C p.A422= | Silent (SNP) | VAF 327/1098 reads (30%) | catalogued as rs761975821; called by muse, mutect2, varscan2
- RYR2 | c.1077A>G p.S359= | Silent (SNP) | VAF 179/630 reads (28%) | catalogued as rs727505317; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCYL2 | c.2394A>C p.P798= | Silent (SNP) | VAF 494/744 reads (66%) | called by muse, mutect2, varscan2
- SETD1B | c.1050G>A p.S350= | Silent (SNP) | VAF 293/923 reads (32%) | catalogued as rs1008545789, COSV99930901; called by muse, mutect2, varscan2
- SHC4 | c.918C>T p.Y306= | Silent (SNP) | VAF 301/301 reads (100%) | catalogued as rs553983973, COSV60116557; called by muse, mutect2, varscan2
- SIGLEC14 | c.357C>T p.R119= | Silent (SNP) | VAF 310/491 reads (63%) | called by muse, mutect2, varscan2
- SOX11 | c.72C>T p.G24= | Silent (SNP) | VAF 755/755 reads (100%) | called by muse, mutect2, varscan2
- SPPL2A | c.6G>T p.G2= | Silent (SNP) | VAF 223/530 reads (42%) | called by muse, mutect2, varscan2
- SYNGR4 | c.282C>T p.A94= | Silent (SNP) | VAF 226/775 reads (29%) | catalogued as rs545305567, COSV61225447; called by muse, mutect2, varscan2
- TNXB | c.1197C>T p.C399= | Silent (SNP) | VAF 301/1168 reads (26%) | catalogued as rs1261691508; called by muse, varscan2
- TRIM71 | c.1440C>T p.S480= | Silent (SNP) | VAF 512/823 reads (62%) | catalogued as rs753096691, COSV67472820; called by muse, mutect2, varscan2
- ZNF611 | c.1581A>G p.T527= | Silent (SNP) | VAF 211/712 reads (30%) | called by muse, mutect2, varscan2
- ZNF780A | c.714C>G p.R238= | Silent (SNP) | VAF 264/843 reads (31%) | called by muse, mutect2, varscan2
- SLC9A1 | c.1485+182G>T | Intron (SNP) | VAF 306/306 reads (100%) | catalogued as rs920230886; called by muse, mutect2, varscan2
